Somatic mutation profile of tumor specimen MMRF_2682_1_BM_CD138pos (aliquot MMRF_2682_1_BM_CD138pos_T1_KHS5U_L14253) from MMRF case MMRF_2682, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.1 years (21,939 days).
Specimen MMRF_2682_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efd2e3d4-a565-445c-87df-055eba5f724e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2682_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2682_1_PB_WBC_C3_KHS5U_L14254; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29f536d2-b259-4f18-bcf1-f21cbee5fc27

The open-access MAF lists 118 somatic variants for this specimen: 47 protein-altering or splice-affecting, 18 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 29, Silent 18, Intron 13, RNA 4, 5'UTR 3, 5'Flank 2, 3'Flank 2, Translation Start Site 1, In Frame Del 1, Nonstop Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2339G>A p.R780K | Missense Mutation (SNP) | VAF 45/115 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705570, COSV66707409; called by muse, mutect2, varscan2
- ANKRD13C | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.2); catalogued as rs946196088; called by muse, mutect2, varscan2
- CCPG1 | c.1115G>T p.R372M | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV60524036; called by muse, mutect2
- DIS3 | c.1436A>C p.D479A | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705800, COSV66705888; called by muse, mutect2, varscan2
- IGHV2-70 | c.247T>C p.S83P | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs544603085; called by muse, varscan2
- IRF2BP2 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs1306470116, COSV64014886; called by muse, mutect2, varscan2
- IRX5 | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as rs757773594; called by muse, mutect2, varscan2
- PRKD2 | c.2038G>A p.V680M | Missense Mutation (SNP) | VAF 42/56 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52185946; called by muse, mutect2, varscan2
- SLIT2 | c.1126C>A p.L376I | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56570637, COSV56582365; called by muse, mutect2
- SPAG11B | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 88/257 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.949); catalogued as rs1405712841; called by muse, mutect2, varscan2
- TRPC4 | c.2921C>A p.T974N (on ENST00000379705 / NM_016179.4; = p.T979N on NM_003306.3) | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.245); catalogued as COSV100156035; called by muse, mutect2, varscan2
- ZNF646 | c.3157C>T p.R1053C | Missense Mutation (SNP) | VAF 94/186 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as rs762178967; called by muse, mutect2, varscan2
- ZSCAN5C | c.1238C>T p.T413M | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.236); catalogued as rs763155291; called by muse, mutect2, varscan2
- ASB17 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BACH1 | c.1736T>G p.L579R | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CADPS2 | c.1692A>C p.E564D | Missense Mutation (SNP) | VAF 70/143 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- DALRD3 | c.352G>T p.V118F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- ECPAS | c.206T>A p.I69K | Missense Mutation (SNP) | VAF 104/316 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- EEF1G | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.58); called by muse, mutect2
- FGFR3 | c.778_801del p.P260_L267del | In Frame Del (DEL) | VAF 34/267 reads (13%) | called by mutect2, pindel, varscan2
- FZD10 | c.403del p.R135Gfs*48 | Frame Shift Del (DEL) | VAF 334/780 reads (43%) | called by mutect2, varscan2
- FZD4 | c.234G>T p.Q78H | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FZD4 | c.233A>C p.Q78P | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IFIT1B | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- IGKV1-33 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 16/42 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- IGSF11 | c.1265C>T p.P422L (on ENST00000393775 / NM_001015887.3; = p.P421L on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNH5 | c.1021T>G p.Y341D | Missense Mutation (SNP) | VAF 76/125 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNJ15 | c.288A>C p.E96D | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.253); called by muse, mutect2
- LRRTM4 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MRC1 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- MTO1 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.012); called by muse, mutect2
- PCDH11Y | c.3284C>T p.P1095L | Missense Mutation (SNP) | VAF 53/71 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- PGAP2 | c.758G>T p.R253L (on ENST00000463452 / NM_001346398.2; = p.R314L on NM_014489.4) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- PNPLA8 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RALGDS | c.1915T>G p.Y639D | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- RNF135 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ROBO1 | c.3796T>G p.S1266A | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.222); called by muse, mutect2
- SEC24C | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 116/261 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- SH2D4A | c.575A>C p.K192T | Missense Mutation (SNP) | VAF 13/331 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- SLC4A1 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SNX31 | c.1313_*8del | Nonstop Mutation (DEL) | VAF 46/378 reads (12%) | called by mutect2, pindel
- STPG3 | c.709A>T p.I237F | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- TLCD4-RWDD3 | c.592T>A p.S198T | Missense Mutation (SNP) | VAF 12/230 reads (5%) | PolyPhen benign (0.184); called by muse, mutect2
- TRAF3 | c.1393A>G p.M465V | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.526); called by muse, mutect2
- TRPM3 | c.4883C>T p.S1628F (on ENST00000357533 / NM_001366142.2; = p.S1483F on NM_020952.6) | Missense Mutation (SNP) | VAF 32/392 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2
- ZC3H12D | c.896C>G p.P299R | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2
- ZNF488 | c.877C>T p.H293Y | Missense Mutation (SNP) | VAF 93/321 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARPC4 | c.63C>T p.C21= | Silent (SNP) | VAF 113/244 reads (46%) | called by muse, mutect2, varscan2
- BBS12 | c.1992C>T p.D664= | Silent (SNP) | VAF 25/366 reads (7%) | catalogued as rs1553941594; called by muse, mutect2
- BCAS1 | c.639G>A p.Q213= | Silent (SNP) | VAF 8/223 reads (4%) | called by muse, mutect2
- BEND3 | c.2094T>C p.F698= | Silent (SNP) | VAF 44/95 reads (46%) | catalogued as rs782745422; called by muse, mutect2, varscan2
- CAPNS1 | c.141C>T p.G47= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs17879825; called by muse, varscan2
- CSTF3 | c.705C>T p.P235= | Silent (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2, varscan2
- GXYLT2 | c.984C>T p.L328= | Silent (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2
- H2BC11 | c.276C>T p.S92= | Silent (SNP) | VAF 8/198 reads (4%) | catalogued as rs925199846; called by muse, mutect2
- LANCL1 | c.501G>A p.K167= | Silent (SNP) | VAF 13/223 reads (6%) | catalogued as COSV52066438; called by muse, mutect2
- LOXHD1 | c.2361C>T p.R787= | Silent (SNP) | VAF 25/132 reads (19%) | catalogued as rs1056635385; called by muse, mutect2, varscan2
- OR10A7 | c.559C>T p.L187= | Silent (SNP) | VAF 12/288 reads (4%) | catalogued as rs1278982378; called by muse, mutect2
- PDE11A | c.966A>G p.S322= | Silent (SNP) | VAF 155/312 reads (50%) | called by muse, mutect2, varscan2
- PKNOX2 | c.639C>A p.P213= | Silent (SNP) | VAF 27/370 reads (7%) | called by muse, mutect2
- PRSS16 | c.936C>T p.C312= | Silent (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2
- SBK2 | c.141G>T p.T47= | Silent (SNP) | VAF 40/130 reads (31%) | catalogued as COSV100704985, COSV60014806; called by muse, mutect2, varscan2
- SCIN | c.699A>G p.G233= | Silent (SNP) | VAF 140/321 reads (44%) | called by muse, mutect2, varscan2
- SEMA3A | c.1803G>A p.S601= | Silent (SNP) | VAF 60/126 reads (48%) | catalogued as rs773851451; called by muse, mutect2, varscan2
- SPOCD1 | c.1278G>A p.K426= | Silent (SNP) | VAF 37/115 reads (32%) | called by muse, mutect2, varscan2
- ACAD8 | c.*607T>A | 3'UTR (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- ACTB | c.-27-170T>C | Intron (SNP) | VAF 66/164 reads (40%) | called by muse, varscan2
- ACTB | c.-27-236C>T | Intron (SNP) | VAF 32/66 reads (48%) | catalogued as rs567797346; called by muse, varscan2
- AMZ2P1 | n.1536G>A | RNA (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- ARHGAP10 | c.*220C>A | 3'UTR (SNP) | VAF 40/170 reads (24%) | called by muse, mutect2, varscan2
- C5orf15 | c.*166T>A | 3'UTR (SNP) | VAF 112/253 reads (44%) | called by muse, mutect2, varscan2
- CACNG2 | c.-248G>A | 5'UTR (SNP) | VAF 64/112 reads (57%) | called by muse, mutect2, varscan2
- CDC42BPA | c.*1906T>C | 3'UTR (SNP) | VAF 10/226 reads (4%) | called by muse, mutect2
- CHML | c.*201T>A | 3'UTR (SNP) | VAF 5/52 reads (10%) | called by muse, varscan2
- CMAHP | n.1315C>G | RNA (SNP) | VAF 30/261 reads (11%) | called by muse, mutect2, varscan2
- CMAHP | n.654A>T | RNA (SNP) | VAF 9/280 reads (3%) | called by muse, mutect2
- DNMT1 | c.4245+21C>T | Intron (SNP) | VAF 32/66 reads (48%) | catalogued as rs942646868; called by muse, mutect2, varscan2
- EPHA5 | c.*3673del | 3'UTR (DEL) | VAF 21/72 reads (29%) | called by mutect2, pindel, varscan2
- ESYT3 | c.1591-62T>A | Intron (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- GDAP1 | c.*854C>T | 3'UTR (SNP) | VAF 45/90 reads (50%) | called by muse, mutect2
- GLMP | chr1:156292687 G>A | 3'Flank (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- IGF1R | c.*2505A>C | 3'UTR (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- IGSF9 | c.1105-15T>C | Intron (SNP) | VAF 11/195 reads (6%) | called by muse, mutect2
- KCNAB1 | chr3:156538612 A>C | 3'Flank (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2
- KCNAB2 | c.*1490G>A | 3'UTR (SNP) | VAF 4/86 reads (5%) | called by muse, mutect2
- KIAA0319 | c.*1350G>T | 3'UTR (SNP) | VAF 5/103 reads (5%) | called by muse, mutect2
- KIF7 | c.3319-90C>T | Intron (SNP) | VAF 37/108 reads (34%) | called by muse, mutect2, varscan2
- LMNA | c.1969-55G>A | Intron (SNP) | VAF 35/110 reads (32%) | called by muse, mutect2, varscan2
- LONRF2 | c.*7216G>T | 3'UTR (SNP) | VAF 50/125 reads (40%) | called by muse, mutect2, varscan2
- METTL25 | c.1478+162A>T | Intron (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- MTMR2 | c.262+26T>C | Intron (SNP) | VAF 100/253 reads (40%) | called by muse, mutect2, varscan2
- MXRA8 | chr1:1361493 T>G | 5'Flank (SNP) | VAF 105/232 reads (45%) | called by muse, mutect2, varscan2
- MZT2A | c.319+1192T>C | Intron (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- NAV3 | c.6519-148C>T | Intron (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- OPHN1 | c.1276+126A>C | Intron (SNP) | VAF 9/12 reads (75%) | called by muse, mutect2
- PDPN | c.*1489T>G | 3'UTR (SNP) | VAF 29/80 reads (36%) | catalogued as rs918872029; called by muse, mutect2, varscan2
- PI4K2B | c.*1037G>A | 3'UTR (SNP) | VAF 29/74 reads (39%) | called by muse, mutect2, varscan2
- PNRC2 | c.*1057A>G | 3'UTR (SNP) | VAF 36/118 reads (31%) | catalogued as rs1388797694; called by muse, mutect2, varscan2
- PRPF38A | c.*866G>T | 3'UTR (SNP) | VAF 14/179 reads (8%) | called by muse, mutect2
- PRRG3 | c.*2572G>A | 3'UTR (SNP) | VAF 109/118 reads (92%) | called by muse, mutect2, varscan2
- RAB4A | c.-19A>T | 5'UTR (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- RALGAPA1 | chr14:35809305 del G | 5'Flank (DEL) | VAF 38/108 reads (35%) | called by mutect2, pindel, varscan2
- RORA | c.*3802T>C | 3'UTR (SNP) | VAF 12/40 reads (30%) | called by mutect2, varscan2
- RUNX3 | c.*208G>A | 3'UTR (SNP) | VAF 142/294 reads (48%) | called by muse, mutect2, varscan2
- SCYL2 | c.*522dup | 3'UTR (INS) | VAF 23/74 reads (31%) | called by mutect2, pindel, varscan2
- SLC6A19 | c.*335T>C | 3'UTR (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- SLC7A11 | c.*820G>A | 3'UTR (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- SOHLH2 | c.*455C>A | 3'UTR (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- SPATA31D5P | n.667C>T | RNA (SNP) | VAF 10/207 reads (5%) | called by muse, mutect2
- ST3GAL2 | c.*448G>C | 3'UTR (SNP) | VAF 12/143 reads (8%) | called by muse, mutect2
- STUM | c.*3003C>T | 3'UTR (SNP) | VAF 24/358 reads (7%) | called by muse, mutect2
- THY1 | c.38-10C>G | Intron (SNP) | VAF 35/66 reads (53%) | called by muse, mutect2, varscan2
- TMEM236 | c.*995G>A | 3'UTR (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2
- TSN | c.*833G>A | 3'UTR (SNP) | VAF 46/139 reads (33%) | catalogued as rs932555388; called by muse, mutect2, varscan2
- TUBA1B | c.-41T>A | 5'UTR (SNP) | VAF 73/159 reads (46%) | called by muse, mutect2, varscan2
- UNC119 | c.*258G>T | 3'UTR (SNP) | VAF 21/175 reads (12%) | catalogued as rs1379936177; called by muse, mutect2, varscan2
- ZBTB6 | c.*2654T>C | 3'UTR (SNP) | VAF 49/136 reads (36%) | called by muse, mutect2, varscan2
- ZC3H14 | c.*10783G>A | 3'UTR (SNP) | VAF 57/87 reads (66%) | called by muse, mutect2, varscan2
